Gene-level copy-number profile of tumor specimen C3L-04072-01 from CPTAC case C3L-04072, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 55.9 years (20,413 days).
Specimen C3L-04072-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f37a770a-0458-4781-aeb8-035bdd032933.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04072-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/9edda044-b316-4899-83ac-530c3cd84831

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 584; copy number 1: 14,591; copy number 2: 42,123; copy number 3: 782; copy number 4: 487; copy number 5: 347.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr9:21,695,176–22,029,594, 10 genes (within-gene range 0–1): KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:27,245,680–27,573,866, 8 genes: LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72.
- chr18:50,959,267–51,283,896, 7 genes: Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P.
- chr19:6,259,157–6,940,459, 41 genes (within-gene range 0–1): AC011471.2, AC011471.3, ACER1, AC011491.3, CLPP, ALKBH7, PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1, KHSRP, MIR3940, SLC25A41, SLC25A23, CRB3, DENND1C, AC010503.4, TUBB4A, AC010503.2, AC010503.1, TNFSF9, AC010503.3, CLIC4P2, Y_RNA, CD70, RPL7P50, TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 347 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:12,310–991,190, 28 genes, copy number 5 (within-gene range 4–5): DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr12:1,380,060–9,845,007, 319 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
